CPTAC case C3L-00359 — Kidney — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/67e289f3-5395-4f2c-b1d2-344bd988b92a

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1943; Vital status: Dead; Days to death: 1,779 days (4.9 years); Year of death: 2021; Cause of death: Cancer Related.

Diagnoses (1)
1. Renal cell carcinoma, NOS: ICD-O-3 morphology code: 8312/3; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Age at diagnosis: 73.5 years (26,864 days); Year of diagnosis: 2016; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T1a; AJCC pathologic N: NX; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; Tumor grade: G1; Residual disease: R0; Last known disease status: With tumor; Days to last known disease status: 1,779 days (4.9 years); Progression or recurrence: yes; Days to recurrence: 1,402 days (3.8 years); Days to last follow up: 1,779 days (4.9 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 3 cm; Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 0; Margin status: Uninvolved; Sarcomatoid present: No.

Follow-up (6 entries)
- Days to follow up: 384 days (1.1 years); Disease response: Tumor Free.
- Days to follow up: 713 days (2.0 years); Disease response: Tumor Free.
- Days to follow up: 1,064 days (2.9 years); Disease response: Tumor Free.
- Days to follow up: 1,442 days (3.9 years); Disease response: With Tumor.
- Days to follow up: 1,779 days (4.9 years); Disease response: With Tumor.
- Days to follow up: 1,779 days (4.9 years); Disease response: Progressive Disease; Progression or recurrence: Yes; Days to recurrence: 1,402 days (3.8 years).

Other clinical attributes
- Weight: 117 kg; Height: 165.1 cm; BMI: 42.92; Comorbidities: Hypothyroidism.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 64.5; Cigarettes per day: 30; Tobacco smoking onset year: 1960; Tobacco smoking quit year: 2003; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker; Exposure duration years: 43.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-00359-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 480 mg; Time between excision and freezing: 19 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-00359-21: Section location: Lower pole; Percent tumor nuclei: 95; Percent necrosis: 0.
- Sample C3L-00359-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 345 mg.
- Sample C3L-00359-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 450 mg.
- Sample C3L-00359-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
